Somatic mutation profile of tumor specimen ALCH-B0FS-TTP1-A (aliquot ALCH-B0FS-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0FS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 64.3 years (23,494 days).
Specimen ALCH-B0FS-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5023e464-bd58-4da9-9947-e38a80d7ae5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0FS-NB1-A (Blood Derived Normal), aliquot ALCH-B0FS-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a377a615-7365-4475-8114-05422784689c

The open-access MAF lists 301 somatic variants for this specimen: 189 protein-altering or splice-affecting, 55 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 163, Silent 55, Intron 18, 3'UTR 17, Nonsense Mutation 11, RNA 9, Frame Shift Del 8, 5'UTR 7, 5'Flank 4, Splice Site 4, 3'Flank 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ2 | c.1342C>T p.R448* (on ENST00000359125 / NM_172107.4; = p.R420* on NM_004518.6) | Nonsense Mutation (SNP) | VAF 186/383 reads (49%) | catalogued as rs118192226, CM033619, COSV100609128; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCDH15 | c.299del p.G100Efs*10 | Frame Shift Del (DEL) | VAF 153/362 reads (42%) | catalogued as rs1554940316, COSV57273159; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- RB1 | c.1215+1G>A p.X405_splice | Splice Site (SNP) | VAF 56/143 reads (39%) | hotspot (GDC flag); catalogued as rs587776783, CS890133, CS982341, COSV57294684, COSV57294939, COSV57306748; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.463A>C p.T155P | Missense Mutation (SNP) | VAF 95/167 reads (57%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV52661985, COSV52698075, COSV52994812, COSV53498723; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2939A>C p.Y980S | Missense Mutation (SNP) | VAF 92/285 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54455715; called by muse, mutect2, varscan2
- AGRN | c.5597C>A p.T1866N | Missense Mutation (SNP) | VAF 126/521 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs938582420; called by muse, mutect2, varscan2
- AL139011.2 | c.577A>G p.R193G | Missense Mutation (SNP) | VAF 14/172 reads (8%) | catalogued as rs1165967149; called by muse, mutect2
- ALG14 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 630/854 reads (74%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.749); catalogued as rs1014644772, COSV64634541; called by muse, mutect2, varscan2
- ANKRD30B | c.3505G>T p.E1169* | Nonsense Mutation (SNP) | VAF 86/174 reads (49%) | catalogued as COSV100271384; called by muse, mutect2, varscan2
- APOBR | c.3097C>A p.P1033T (on ENST00000431282; = p.P1042T on NM_018690.4) | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100112819; called by muse, mutect2, varscan2
- ARHGEF9 | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.164); catalogued as rs1556300901; called by muse, mutect2, varscan2
- ARHGEF9 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.134); catalogued as rs1377348559, COSV53641109, COSV53641521; called by muse, mutect2, varscan2
- B3GNT8 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 96/164 reads (59%) | SIFT tolerated (0.24); PolyPhen benign (0.133); catalogued as COSV54198339; called by muse, mutect2, varscan2
- BTN1A1 | c.345_346del p.R115Sfs*3 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | catalogued as rs747589600; called by pindel, varscan2
- CCDC141 | c.2558C>T p.S853L | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99836505; called by muse, mutect2, varscan2
- CPN2 | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as rs759267777; called by muse, varscan2
- DPYD | c.2992A>T p.I998F | Missense Mutation (SNP) | VAF 664/924 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs745982505; called by muse, mutect2, varscan2
- DST | c.3831G>T p.Q1277H (on ENST00000361203 / NM_001374722.1; = p.Q951H on NM_001723.6) | Missense Mutation (SNP) | VAF 149/281 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs554214573, COSV99758607; called by muse, mutect2, varscan2
- EDEM3 | c.854A>G p.D285G | Missense Mutation (SNP) | VAF 85/205 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs942092624; called by muse, mutect2, varscan2
- EIF2S3B | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 258/400 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs922824216; called by muse, mutect2, varscan2
- FAM131A | c.956C>T p.S319F (on ENST00000310585; = p.S350F on NM_144635.5) | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1406341926; called by muse, mutect2, varscan2
- FNDC1 | c.477C>G p.N159K | Missense Mutation (SNP) | VAF 149/206 reads (72%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as rs747651973, COSV51931308; called by muse, mutect2, varscan2
- FOXA2 | c.1351C>T p.R451W (on ENST00000377115 / NM_153675.3; = p.R457W on NM_021784.5) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65796127; called by muse, mutect2, varscan2
- FRMD6 | c.1206G>T p.K402N (on ENST00000344768 / NM_001267046.2; = p.K394N on NM_152330.4) | Missense Mutation (SNP) | VAF 103/161 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); catalogued as COSV100656261; called by muse, mutect2, varscan2
- GPR50 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.035); catalogued as rs1042295670; called by muse, mutect2, varscan2
- ICE1 | c.4532G>T p.R1511L | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV56833008; called by muse, varscan2
- IK | c.177-4C>T | Splice Region (SNP) | VAF 135/236 reads (57%) | catalogued as rs752500995; called by muse, mutect2, varscan2
- IRF4 | c.1123G>A p.G375S | Missense Mutation (SNP) | VAF 53/299 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs1169247876, COSV66704779; called by muse, mutect2, varscan2
- KIAA1109 | c.14508C>G p.S4836R | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as rs201636574; called by muse, mutect2, varscan2
- LRRC26 | c.18G>T p.W6C | Missense Mutation (SNP) | VAF 62/91 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.187); catalogued as rs760990925; called by muse, mutect2, varscan2
- MC2R | c.254T>C p.I85T | Missense Mutation (SNP) | VAF 125/772 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs770532169; called by muse, mutect2, varscan2
- MICU1 | c.1414G>T p.A472S (on ENST00000361114 / NM_001195518.2; = p.A478S on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV63145447; called by muse, mutect2, varscan2
- MRPS35 | c.636C>A p.C212* | Nonsense Mutation (SNP) | VAF 119/400 reads (30%) | catalogued as COSV50011899; called by muse, mutect2, varscan2
- MYO16 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 40/326 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV99194984; called by muse, varscan2
- NAA35 | c.2096G>T p.G699V | Missense Mutation (SNP) | VAF 31/288 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV64486269; called by muse, mutect2, varscan2
- NCKAP1L | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779642333, COSV53206082; called by muse, mutect2, varscan2
- NDST1 | c.1331A>G p.Y444C | Missense Mutation (SNP) | VAF 16/225 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.464); catalogued as COSV55787553; called by muse, mutect2
- NIN | c.3395C>T p.T1132M | Missense Mutation (SNP) | VAF 50/301 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs139379777; called by muse, mutect2, varscan2
- NPR2 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 66/276 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs748364573; called by muse, mutect2, varscan2
- OR2T3 | c.823C>G p.Q275E | Missense Mutation (SNP) | VAF 44/298 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as COSV62081913; called by muse, mutect2, varscan2
- OR4C13 | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 103/230 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.12); catalogued as COSV73648914; called by muse, mutect2, varscan2
- OR5M8 | c.647C>A p.S216Y | Missense Mutation (SNP) | VAF 100/282 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV59117762; called by muse, mutect2, varscan2
- PANK2 | c.1660G>A p.E554K (on ENST00000316562 / NM_153638.3; = p.E263K on NM_024960.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 128/992 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1328306876, COSV57253664; called by muse, mutect2, varscan2
- PCF11 | c.3528G>C p.Q1176H | Missense Mutation (SNP) | VAF 67/241 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100018987; called by muse, mutect2, varscan2
- PKHD1 | c.1912A>G p.M638V | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765250071; called by muse, mutect2, varscan2
- PRDM7 | c.1072G>T p.G358W | Missense Mutation (SNP) | VAF 115/492 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57986167; called by muse, varscan2
- PROM2 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 209/331 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs768118946; called by mutect2, varscan2
- RAG1 | c.1202C>T p.S401L | Missense Mutation (SNP) | VAF 92/429 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs1385203770, COSV55029241; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RHOBTB1 | c.2008C>T p.R670* | Nonsense Mutation (SNP) | VAF 26/252 reads (10%) | catalogued as rs148931110, COSV61959068; called by muse, mutect2
- RLIM | c.1564G>T p.E522* | Nonsense Mutation (SNP) | VAF 106/229 reads (46%) | catalogued as rs1030558036; called by muse, mutect2, varscan2
- RTP5 | c.1141G>T p.V381F | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV100574813; called by muse, mutect2, varscan2
- SCN7A | c.3610G>A p.G1204R | Missense Mutation (SNP) | VAF 146/220 reads (66%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.484); catalogued as rs77645356; called by muse, mutect2, varscan2
- SEMA5A | c.3029C>G p.S1010* | Nonsense Mutation (SNP) | VAF 69/865 reads (8%) | catalogued as COSV101228644; called by muse, mutect2
- SOS2 | c.88G>T p.V30F | Missense Mutation (SNP) | VAF 102/171 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs758144954; called by mutect2, varscan2
- SPDYE5 | c.1103G>A p.C368Y | Missense Mutation (SNP) | VAF 37/288 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.852); catalogued as rs1347642544; called by muse, varscan2
- SPIN4 | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 50/300 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100633412; called by muse, mutect2, varscan2
- SYNGR3 | c.480+1G>T p.X160_splice | Splice Site (SNP) | VAF 15/45 reads (33%) | catalogued as rs769326172; called by muse, mutect2, varscan2
- TBC1D15 | c.1387C>T p.L463F | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV59848699; called by muse, mutect2, varscan2
- TESPA1 | c.1505G>A p.R502H (on ENST00000316577 / NM_001098815.3; = p.R364H on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 125/252 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs772643563; called by muse, mutect2, varscan2
- TMEM132C | c.1913G>T p.G638V | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59412661; called by muse, varscan2
- TMEM132C | c.2498G>A p.R833H | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.886); catalogued as rs750924400; called by muse, mutect2, varscan2
- TNNT2 | c.670G>A p.E224K (on ENST00000236918; = p.E221K on NM_000364.4) | Missense Mutation (SNP) | VAF 179/461 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs769128006; called by muse, mutect2, varscan2
- TPMT | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 68/756 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.458); catalogued as rs772470049; called by muse, mutect2
- TRIM77 | c.531G>T p.M177I | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.068); catalogued as COSV68065961; called by muse, varscan2
- TRPC3 | c.2267T>C p.V756A (on ENST00000379645 / NM_001366479.2; = p.V683A on NM_003305.2) | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as rs1461323686; called by muse, mutect2, varscan2
- UBE2G2 | c.235C>T p.H79Y | Missense Mutation (SNP) | VAF 180/302 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100446078; called by muse, mutect2, varscan2
- UBE3A | c.1259A>G p.K420R | Missense Mutation (SNP) | VAF 91/482 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs781211197; called by muse, mutect2, varscan2
- USP5 | c.2458G>A p.V820I (on ENST00000229268 / NM_001098536.2; = p.V797I on NM_003481.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.591); catalogued as rs782621306, COSV57540253; called by muse, mutect2, varscan2
- VNN1 | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 127/235 reads (54%) | SIFT tolerated (0.36); PolyPhen benign (0.027); catalogued as COSV63389447; called by muse, mutect2, varscan2
- VPS35L | c.1609C>A p.R537S | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51991854; called by muse, mutect2, varscan2
- XKR6 | c.1109C>T p.S370F | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58654398; called by muse, mutect2, varscan2
- ZNHIT2 | c.827A>C p.H276P | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs971314633; called by muse, mutect2, varscan2
- AASDH | c.3028C>G p.L1010V | Missense Mutation (SNP) | VAF 65/242 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- ACSL1 | c.1824A>T p.L608F | Missense Mutation (SNP) | VAF 75/316 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ACSL1 | c.1823T>A p.L608* | Nonsense Mutation (SNP) | VAF 75/316 reads (24%) | called by muse, mutect2, varscan2
- ACTN2 | c.1749G>C p.E583D | Missense Mutation (SNP) | VAF 61/331 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADGRL3 | c.2255T>C p.L752P (on ENST00000506720 / NM_001322402.2; = p.L684P on NM_015236.6) | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADRA2C | c.695_696del p.R232Hfs*97 | Frame Shift Del (DEL) | VAF 22/71 reads (31%) | called by pindel, varscan2
- AGBL3 | c.703T>C p.Y235H | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- ANK2 | c.131T>C p.L44P | Missense Mutation (SNP) | VAF 66/282 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ANK2 | c.7115C>A p.S2372Y | Missense Mutation (SNP) | VAF 55/233 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- BMP7 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 110/694 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BMPER | c.1991A>G p.H664R | Missense Mutation (SNP) | VAF 152/259 reads (59%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- BTBD17 | c.725G>T p.R242L | Missense Mutation (SNP) | VAF 169/255 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- C19orf73 | c.80G>T p.R27L | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CARMIL1 | c.957del p.V322* | Frame Shift Del (DEL) | VAF 72/181 reads (40%) | called by mutect2, pindel, varscan2
- CCDC71L | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- CDKL5 | c.2981G>T p.G994V | Missense Mutation (SNP) | VAF 74/236 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CECR2 | c.443G>A p.G148D | Missense Mutation (SNP) | VAF 38/272 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP41 | c.351G>C p.E117D | Missense Mutation (SNP) | VAF 55/420 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- COL10A1 | c.961G>C p.A321P | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL6A5 | c.3207G>T p.K1069N | Missense Mutation (SNP) | VAF 276/517 reads (53%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CPS1 | c.1980A>T p.T660= | Splice Region (SNP) | VAF 118/221 reads (53%) | called by muse, mutect2, varscan2
- CSF2RB | c.732G>T p.Q244H | Missense Mutation (SNP) | VAF 48/275 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DENR | c.303G>C p.R101S | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- DNAH3 | c.10678C>A p.P3560T | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- DPP8 | c.2301G>C p.Q767H (on ENST00000341861 / NM_001320875.2; = p.Q751H on NM_130434.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- EPHB4 | c.2434G>A p.E812K | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERCC6L | c.2729C>T p.S910L | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- EVC | c.2479A>G p.K827E | Missense Mutation (SNP) | VAF 88/364 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- FAM209A | c.323A>T p.N108I | Missense Mutation (SNP) | VAF 127/385 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- FAM47B | c.322T>C p.S108P | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- FCGBP | c.1982C>A p.T661N | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- FHL5 | c.415A>G p.T139A | Missense Mutation (SNP) | VAF 27/645 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.14); called by muse, mutect2
- FRAS1 | c.6187G>T p.D2063Y | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GLP2R | c.534G>T p.L178F | Missense Mutation (SNP) | VAF 63/252 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- HAUS7 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 122/456 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HCFC1 | c.5704-2A>G p.X1902_splice | Splice Site (SNP) | VAF 5/13 reads (38%) | called by muse, varscan2
- HDAC6 | c.3044G>C p.G1015A | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HERC2 | c.6474G>T p.Q2158H | Missense Mutation (SNP) | VAF 153/1003 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- HTT | c.3647C>T p.S1216L | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- IGHV3-72 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 121/184 reads (66%) | called by muse, mutect2, varscan2
- IGSF1 | c.2629C>T p.L877F | Missense Mutation (SNP) | VAF 35/259 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IRAK1 | c.263C>A p.T88K | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- ISL1 | c.915G>T p.Q305H | Missense Mutation (SNP) | VAF 430/780 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ITGA4 | c.400C>G p.Q134E | Missense Mutation (SNP) | VAF 88/153 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- ITPKC | c.1237C>T p.Q413* | Nonsense Mutation (SNP) | VAF 66/119 reads (55%) | called by muse, mutect2, varscan2
- KDM6A | c.2762C>G p.P921R | Missense Mutation (SNP) | VAF 33/416 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- KHDRBS3 | c.208T>C p.F70L | Missense Mutation (SNP) | VAF 124/230 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- KIF19 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- KMT2D | c.11391dup p.P3798Afs*214 | Frame Shift Ins (INS) | VAF 11/85 reads (13%) | called by mutect2, pindel, varscan2
- KRT85 | c.1415C>T p.S472L | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KRTAP12-4 | c.152G>C p.G51A | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LAMA1 | c.8543G>T p.R2848M | Missense Mutation (SNP) | VAF 43/298 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- LAMC1 | c.343A>C p.T115P | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRTM1 | c.1540C>A p.Q514K | Missense Mutation (SNP) | VAF 70/102 reads (69%) | SIFT tolerated (1); PolyPhen probably damaging (0.952); called by muse, varscan2
- METTL25 | c.1650G>C p.L550F | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MITF | c.1134C>G p.N378K (on ENST00000448226 / NM_006722.3; = p.N278K on NM_000248.4) | Missense Mutation (SNP) | VAF 148/269 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYH8 | c.1634A>T p.K545M | Missense Mutation (SNP) | VAF 74/121 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- NAV3 | c.5771A>T p.K1924M (on ENST00000397909 / NM_001024383.2; = p.K1902M on NM_014903.6) | Missense Mutation (SNP) | VAF 181/357 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- NDST4 | c.2370del p.R791Vfs*8 | Frame Shift Del (DEL) | VAF 49/219 reads (22%) | called by mutect2, pindel, varscan2
- NLRP4 | c.1702C>T p.Q568* | Nonsense Mutation (SNP) | VAF 63/98 reads (64%) | called by muse, mutect2, varscan2
- NUS1 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 72/149 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- OR52H1 | c.119C>G p.A40G (on ENST00000322653; = p.A46G on NM_001005289.1) | Missense Mutation (SNP) | VAF 70/402 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- OR6C76 | c.503C>A p.S168Y | Missense Mutation (SNP) | VAF 129/261 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- OSBPL3 | c.1185A>T p.K395N | Missense Mutation (SNP) | VAF 96/146 reads (66%) | SIFT tolerated (0.1); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- PCDHGA5 | c.1532C>A p.T511N | Missense Mutation (SNP) | VAF 88/140 reads (63%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- PCDHGB3 | c.1469A>T p.Y490F | Missense Mutation (SNP) | VAF 92/332 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PDE4B | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 74/314 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- PPP1R3F | c.1615C>A p.P539T | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PPP1R9A | c.1936G>C p.V646L | Missense Mutation (SNP) | VAF 73/133 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRKCG | c.1436G>C p.R479T | Missense Mutation (SNP) | VAF 123/479 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRPF38A | c.710G>T p.R237L | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- PSKH2 | c.829G>C p.G277R | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- RARB | c.1159A>G p.I387V (on ENST00000383772 / NM_001290216.2; = p.I380V on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/125 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- RBBP6 | c.4259A>T p.K1420M | Missense Mutation (SNP) | VAF 81/302 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RC3H2 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 198/302 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- RIMBP2 | c.1323C>G p.F441L | Missense Mutation (SNP) | VAF 94/461 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RPUSD3 | c.403G>C p.G135R | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- RTL4 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RYR2 | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 172/443 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- SCAF11 | c.3952G>A p.V1318I | Missense Mutation (SNP) | VAF 78/411 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- SCG3 | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 87/278 reads (31%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCN11A | c.3699G>T p.W1233C | Missense Mutation (SNP) | VAF 103/161 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SELENOK | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SERINC3 | c.971C>G p.T324S | Missense Mutation (SNP) | VAF 105/415 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SERPINB4 | c.912G>A p.M304I | Missense Mutation (SNP) | VAF 168/572 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- SETD1A | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SF1 | c.1884G>T p.M628I | Missense Mutation (SNP) | VAF 78/271 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- SH3BP5 | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 148/218 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, varscan2
- SIPA1L2 | c.1601C>G p.A534G | Missense Mutation (SNP) | VAF 91/205 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- SLC10A3 | c.454G>C p.A152P | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC17A3 | c.770T>A p.L257Q | Missense Mutation (SNP) | VAF 64/399 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLCO1C1 | c.1164del p.S389Pfs*6 | Frame Shift Del (DEL) | VAF 114/224 reads (51%) | called by mutect2, varscan2
- SLITRK2 | c.1858G>T p.V620F | Missense Mutation (SNP) | VAF 141/414 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPESP1 | c.611G>A p.G204D | Missense Mutation (SNP) | VAF 150/414 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SPHK1 | c.1032G>C p.L344F (on ENST00000392496 / NM_001355139.2; = p.L358F on NM_021972.4) | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.463); called by muse, mutect2
- SSTR1 | c.985A>C p.N329H | Missense Mutation (SNP) | VAF 69/156 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- STARD9 | c.8689C>A p.P2897T | Missense Mutation (SNP) | VAF 89/260 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- STAT4 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 81/134 reads (60%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.447); called by muse, varscan2
- SULF2 | c.87C>A p.H29Q | Missense Mutation (SNP) | VAF 29/238 reads (12%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- TECTA | c.2248T>G p.L750V | Missense Mutation (SNP) | VAF 177/308 reads (57%) | SIFT tolerated (0.86); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TENM3 | c.373G>T p.V125L | Missense Mutation (SNP) | VAF 67/253 reads (26%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- TENT5D | c.458C>G p.T153S | Missense Mutation (SNP) | VAF 61/334 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TMEM236 | c.809A>T p.Y270F | Missense Mutation (SNP) | VAF 303/552 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TWF1 | c.104-2A>G p.X35_splice | Splice Site (SNP) | VAF 142/328 reads (43%) | called by muse, mutect2, varscan2
- UBR5 | c.6989T>G p.L2330* | Nonsense Mutation (SNP) | VAF 363/664 reads (55%) | called by muse, mutect2, varscan2
- UGGT2 | c.3704C>T p.S1235L | Missense Mutation (SNP) | VAF 133/254 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- UNKL | c.991C>A p.P331T | Missense Mutation (SNP) | VAF 88/289 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VASH1 | c.75del p.S26Lfs*125 | Frame Shift Del (DEL) | VAF 30/58 reads (52%) | called by mutect2, pindel, varscan2
- VWDE | c.2846del p.G949Afs*69 | Frame Shift Del (DEL) | VAF 42/152 reads (28%) | called by mutect2, pindel, varscan2
- WDR3 | c.302T>C p.V101A | Missense Mutation (SNP) | VAF 55/366 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- XIRP2 | c.5556G>C p.K1852N (on ENST00000628543; = p.K2027N on NM_152381.6) | Missense Mutation (SNP) | VAF 198/340 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- XRN1 | c.4111G>A p.V1371M | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); called by muse, mutect2
- YY1 | c.881G>A p.R294K | Missense Mutation (SNP) | VAF 112/551 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- ZIC5 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.042); called by muse, varscan2
- ZNF75D | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF79 | c.766A>G p.R256G | Missense Mutation (SNP) | VAF 79/184 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- ZNF804A | c.683C>A p.S228Y | Missense Mutation (SNP) | VAF 178/312 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACACA | c.426A>T p.P142= | Silent (SNP) | VAF 90/364 reads (25%) | called by muse, mutect2, varscan2
- ADAD2 | c.918G>A p.Q306= (on ENST00000315906 / NM_001145400.2; = p.Q388= on NM_139174.4) | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV51892418; called by muse, mutect2, varscan2
- ADGRG3 | c.1215C>T p.L405= | Silent (SNP) | VAF 23/94 reads (24%) | called by muse, mutect2, varscan2
- AQR | c.3189G>A p.E1063= | Silent (SNP) | VAF 78/262 reads (30%) | called by muse, mutect2, varscan2
- ARHGAP17 | c.1791A>T p.I597= (on ENST00000289968 / NM_001006634.3; = p.I519= on NM_018054.6) | Silent (SNP) | VAF 92/344 reads (27%) | called by muse, mutect2, varscan2
- BCORL1 | c.4539C>T p.A1513= | Silent (SNP) | VAF 28/258 reads (11%) | catalogued as rs771570017; called by muse, mutect2, varscan2
- CCSER1 | c.2445A>T p.S815= | Silent (SNP) | VAF 35/130 reads (27%) | called by muse, mutect2, varscan2
- CFAP47 | c.8058C>A p.V2686= | Silent (SNP) | VAF 22/102 reads (22%) | called by muse, varscan2
- COG4 | c.612A>G p.A204= | Silent (SNP) | VAF 67/240 reads (28%) | called by muse, mutect2, varscan2
- COL4A2 | c.4398A>G p.Q1466= | Silent (SNP) | VAF 47/146 reads (32%) | called by muse, mutect2, varscan2
- DAGLB | c.1500C>A p.L500= | Silent (SNP) | VAF 25/67 reads (37%) | called by muse, mutect2, varscan2
- DOT1L | c.573G>A p.P191= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as rs377172053; called by muse, mutect2, varscan2
- EMC1 | c.186G>T p.V62= | Silent (SNP) | VAF 63/327 reads (19%) | catalogued as COSV100617500; called by muse, mutect2, varscan2
- FANCB | c.2460G>A p.K820= | Silent (SNP) | VAF 59/198 reads (30%) | catalogued as COSV100146656; called by muse, mutect2, varscan2
- FERMT3 | c.261C>T p.A87= | Silent (SNP) | VAF 78/440 reads (18%) | catalogued as rs779540166, COSV54180726; called by muse, mutect2, varscan2
- GK | c.1569A>G p.Q523= (on ENST00000427190 / NM_001205019.2; = p.Q517= on NM_000167.6) | Silent (SNP) | VAF 67/249 reads (27%) | called by muse, mutect2, varscan2
- GZMH | c.136C>A p.R46= | Silent (SNP) | VAF 170/267 reads (64%) | catalogued as rs923264792, COSV53539311; called by muse, mutect2, varscan2
- HEBP2 | c.384C>T p.F128= | Silent (SNP) | VAF 37/233 reads (16%) | catalogued as COSV62928282; called by muse, mutect2, varscan2
- IGSF21 | c.309G>T p.L103= | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as rs1172039863, COSV52125853; called by muse, mutect2, varscan2
- ING5 | c.396G>T p.R132= | Silent (SNP) | VAF 99/177 reads (56%) | called by muse, mutect2, varscan2
- INSRR | c.546T>C p.G182= | Silent (SNP) | VAF 54/128 reads (42%) | called by muse, mutect2, varscan2
- KDM5A | c.567A>G p.K189= | Silent (SNP) | VAF 139/393 reads (35%) | called by muse, mutect2, varscan2
- KIAA1210 | c.1593A>G p.A531= | Silent (SNP) | VAF 83/441 reads (19%) | called by muse, mutect2, varscan2
- LRRD1 | c.417A>T p.L139= | Silent (SNP) | VAF 62/117 reads (53%) | called by muse, mutect2, varscan2
- LYPD3 | c.756C>G p.T252= | Silent (SNP) | VAF 71/117 reads (61%) | called by muse, mutect2, varscan2
- LZTS2 | c.1791G>A p.E597= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as rs557222054; called by muse, mutect2, varscan2
- NEXMIF | c.4278C>T p.F1426= | Silent (SNP) | VAF 141/266 reads (53%) | called by muse, mutect2, varscan2
- NPY2R | c.282G>T p.V94= | Silent (SNP) | VAF 32/121 reads (26%) | called by muse, mutect2, varscan2
- OCA2 | c.2304C>T p.L768= | Silent (SNP) | VAF 53/526 reads (10%) | catalogued as rs1567023092; called by muse, mutect2
- OR2L3 | c.582T>C p.Y194= | Silent (SNP) | VAF 40/244 reads (16%) | catalogued as rs1439770284; called by muse, varscan2
- OR2T4 | c.645T>C p.A215= | Silent (SNP) | VAF 51/191 reads (27%) | catalogued as rs770035271; called by muse, mutect2, varscan2
- OR51E1 | c.360C>A p.A120= | Silent (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- OR5M8 | c.648C>A p.S216= | Silent (SNP) | VAF 97/277 reads (35%) | called by muse, mutect2, varscan2
- PARP8 | c.955C>A p.R319= | Silent (SNP) | VAF 54/422 reads (13%) | catalogued as rs774347413; called by muse, mutect2, varscan2
- PCMTD1 | c.261G>T p.L87= | Silent (SNP) | VAF 88/153 reads (58%) | called by muse, mutect2, varscan2
- POTEB3 | c.936T>A p.A312= | Silent (SNP) | VAF 77/419 reads (18%) | called by muse, mutect2, varscan2
- PPFIA4 | c.3351C>T p.R1117= (on ENST00000447715; = p.R1118= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs781161939, COSV99690300; called by muse, varscan2
- RMC1 | c.1104T>C p.N368= | Silent (SNP) | VAF 63/232 reads (27%) | called by muse, mutect2, varscan2
- RNF182 | c.354G>A p.L118= | Silent (SNP) | VAF 80/146 reads (55%) | called by muse, mutect2, varscan2
- SCARB2 | c.843C>T p.F281= | Silent (SNP) | VAF 44/264 reads (17%) | catalogued as COSV53670789; called by muse, mutect2, varscan2
- SIM2 | c.1764C>T p.A588= | Silent (SNP) | VAF 49/84 reads (58%) | catalogued as rs1213755468; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2127G>A p.R709= (on ENST00000540229 / NM_001371097.1; = p.R648= on NM_001009562.4) | Silent (SNP) | VAF 15/381 reads (4%) | catalogued as COSV67440296; called by muse, mutect2
- STAT4 | c.762G>T p.G254= | Silent (SNP) | VAF 80/132 reads (61%) | called by muse, varscan2
- TBC1D22B | c.33G>A p.K11= | Silent (SNP) | VAF 46/198 reads (23%) | catalogued as COSV60825377; called by muse, mutect2, varscan2
- TENM1 | c.6255C>T p.Y2085= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as rs145948225, COSV64429075; called by muse, mutect2, varscan2
- TG | c.2478G>A p.E826= | Silent (SNP) | VAF 263/522 reads (50%) | called by muse, mutect2, varscan2
- TGM1 | c.2203A>C p.R735= | Silent (SNP) | VAF 38/388 reads (10%) | called by muse, mutect2
- TMEM100 | c.93C>T p.I31= | Silent (SNP) | VAF 40/206 reads (19%) | catalogued as rs1189317788, COSV70117977; called by muse, varscan2
- TNKS1BP1 | c.480G>A p.T160= | Silent (SNP) | VAF 59/230 reads (26%) | catalogued as rs375862296; called by muse, mutect2, varscan2
- TRIOBP | c.5862T>A p.A1954= (on ENST00000644935 / NM_001039141.3; = p.A241= on NM_007032.5) | Silent (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- USH2A | c.9528T>A p.P3176= | Silent (SNP) | VAF 128/300 reads (43%) | called by muse, mutect2, varscan2
- WDR1 | c.1116C>T p.T372= (on ENST00000382452; = p.T232= on NM_005112.5) | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as rs780305268; called by muse, mutect2, varscan2
- XYLT1 | c.1650G>A p.L550= | Silent (SNP) | VAF 42/146 reads (29%) | called by muse, varscan2
- ZAR1 | c.216C>T p.A72= | Silent (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- ZNF74 | c.408G>A p.E136= | Silent (SNP) | VAF 82/231 reads (35%) | called by muse, mutect2, varscan2
- AATK | c.*19C>T | 3'UTR (SNP) | VAF 33/214 reads (15%) | catalogued as rs139976096; called by muse, mutect2, varscan2
- ABCC6P1 | n.1149C>A | RNA (SNP) | VAF 82/298 reads (28%) | called by muse, mutect2, varscan2
- ABI2 | c.1193-5579C>A | Intron (SNP) | VAF 46/361 reads (13%) | catalogued as COSV53689891; called by muse, mutect2, varscan2
- AC244197.3 | c.-1870G>C | 5'UTR (SNP) | VAF 91/362 reads (25%) | called by muse, mutect2, varscan2
- ADAM32 | c.*41C>G | 3'UTR (SNP) | VAF 12/131 reads (9%) | called by muse, mutect2
- AMER1 | c.*3732C>G | 3'UTR (SNP) | VAF 47/188 reads (25%) | called by muse, mutect2, varscan2
- ANO7 | c.2341-24C>G | Intron (SNP) | VAF 9/66 reads (14%) | catalogued as rs772576141; called by mutect2, varscan2
- ARAP2 | c.2442+18A>G | Intron (SNP) | VAF 39/132 reads (30%) | called by muse, mutect2, varscan2
- C19orf12 | c.*293C>A | 3'UTR (SNP) | VAF 90/545 reads (17%) | called by muse, mutect2, varscan2
- C8orf44-SGK3 | c.-349A>T | 5'UTR (SNP) | VAF 275/536 reads (51%) | called by muse, mutect2, varscan2
- CCN6 | c.346+41T>C | Intron (SNP) | VAF 48/180 reads (27%) | catalogued as rs1554312839; called by muse, mutect2, varscan2
- CEP170 | c.*279C>T | 3'UTR (SNP) | VAF 67/331 reads (20%) | called by muse, mutect2, varscan2
- CGREF1 | chr2:27100535 G>T | 3'Flank (SNP) | VAF 101/161 reads (63%) | called by muse, mutect2, varscan2
- CPLX4 | c.*18G>A | 3'UTR (SNP) | VAF 61/266 reads (23%) | called by muse, mutect2, varscan2
- CYP2A6 | c.*3G>C | 3'UTR (SNP) | VAF 16/152 reads (11%) | catalogued as rs756938752; called by mutect2, varscan2
- CYP2A7 | c.*3G>C | 3'UTR (SNP) | VAF 17/65 reads (26%) | catalogued as rs370699685; called by muse, mutect2, varscan2
- DDX41 | c.*178C>T | 3'UTR (SNP) | VAF 50/134 reads (37%) | called by muse, mutect2, varscan2
- DNAH14 | c.1825+642A>G | Intron (SNP) | VAF 39/211 reads (18%) | called by muse, mutect2, varscan2
- DNAJC8 | c.-9G>T | 5'UTR (SNP) | VAF 68/138 reads (49%) | catalogued as rs1249272517; called by muse, mutect2, varscan2
- DNAJC8 | c.-10G>T | 5'UTR (SNP) | VAF 68/135 reads (50%) | called by muse, mutect2, varscan2
- FCRLB | c.575-96C>A | Intron (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- FGF17 | c.-23C>T | 5'UTR (SNP) | VAF 27/111 reads (24%) | called by muse, mutect2, varscan2
- GABRA2 | c.1059+5575C>A | Intron (SNP) | VAF 24/80 reads (30%) | called by muse, varscan2
- GATA4 | chr8:11761497 G>A | 3'Flank (SNP) | VAF 17/76 reads (22%) | catalogued as rs1478592756; called by muse, mutect2, varscan2
- GCSAM | c.99-178C>G | Intron (SNP) | VAF 15/230 reads (7%) | called by muse, mutect2
- GUCY2EP | n.1031G>A | RNA (SNP) | VAF 22/76 reads (29%) | called by muse, varscan2
- GVINP1 | n.5977G>C | RNA (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- IDS | c.418+96C>T | Intron (SNP) | VAF 33/234 reads (14%) | called by muse, mutect2, varscan2
- IGKV1-13 | n.299C>A | RNA (SNP) | VAF 230/406 reads (57%) | called by muse, mutect2, varscan2
- KCND3 | chr1:111991131 C>T | 5'Flank (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- KCNMB2 | c.-5C>G | 5'UTR (SNP) | VAF 24/232 reads (10%) | called by muse, varscan2
- LEPROT | chr1:65420633 G>C | 5'Flank (SNP) | VAF 30/121 reads (25%) | catalogued as rs1233375571; called by muse, mutect2, varscan2
- LILRB5 | c.34+31C>T | Intron (SNP) | VAF 50/85 reads (59%) | called by muse, mutect2, varscan2
- LMF1 | c.193+6686G>C | Intron (SNP) | VAF 37/128 reads (29%) | called by muse, mutect2, varscan2
- MICAL2 | c.3335-23C>T | Intron (SNP) | VAF 48/210 reads (23%) | catalogued as rs373734089; called by muse, mutect2, varscan2
- MIR505 | n.65G>T | RNA (SNP) | VAF 66/144 reads (46%) | called by muse, mutect2, varscan2
- MTARC2 | c.*76G>T | 3'UTR (SNP) | VAF 41/264 reads (16%) | called by muse, mutect2, varscan2
- MTARC2 | c.*77C>G | 3'UTR (SNP) | VAF 41/263 reads (16%) | called by muse, mutect2, varscan2
- MTHFD1 | c.-134A>T | 5'UTR (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
- OR2A13P | n.805C>G | RNA (SNP) | VAF 60/228 reads (26%) | called by muse, mutect2, varscan2
- PCCB | c.373-135T>C | Intron (SNP) | VAF 8/69 reads (12%) | catalogued as rs1463198745; called by muse, mutect2, varscan2
- PDZD4 | c.296+484C>G | Intron (SNP) | VAF 45/156 reads (29%) | called by muse, varscan2
- PPP4R1L | n.1697G>A | RNA (SNP) | VAF 70/474 reads (15%) | called by muse, mutect2, varscan2
- PPP4R4 | c.*19G>T | 3'UTR (SNP) | VAF 103/157 reads (66%) | called by muse, mutect2, varscan2
- PRDM10 | chr11:130003060 G>A | 5'Flank (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- PUDP | c.511-7343C>T | Intron (SNP) | VAF 57/169 reads (34%) | called by muse, mutect2, varscan2
- RALYL | c.-24+602C>T | Intron (SNP) | VAF 191/410 reads (47%) | catalogued as rs371888578; called by muse, mutect2, varscan2
- RP1 | c.*45A>G | 3'UTR (SNP) | VAF 37/243 reads (15%) | catalogued as rs1174763360; called by muse, varscan2
- RRN3P1 | n.3208G>A | RNA (SNP) | VAF 9/34 reads (26%) | called by mutect2, varscan2
- SHROOM4 | c.*328C>T | 3'UTR (SNP) | VAF 70/333 reads (21%) | called by muse, mutect2, varscan2
- SIRT7 | c.*29C>T | 3'UTR (SNP) | VAF 136/563 reads (24%) | called by muse, mutect2, varscan2
- STAG3L2 | n.1023G>T | RNA (SNP) | VAF 26/282 reads (9%) | catalogued as rs1554426472; called by muse, mutect2
- TAZ | c.*470del | 3'UTR (DEL) | VAF 66/248 reads (27%) | catalogued as rs782716746; called by pindel, varscan2
- VPS16 | chr20:2840710 C>T | 5'Flank (SNP) | VAF 114/240 reads (48%) | called by muse, varscan2
- VWCE | c.206-45G>A | Intron (SNP) | VAF 18/104 reads (17%) | catalogued as rs779259554; called by muse, mutect2, varscan2
- YIF1B | c.789+470T>C | Intron (SNP) | VAF 21/241 reads (9%) | catalogued as rs778763323, COSV56649971; called by muse, mutect2
- ZNF99 | c.*3235C>A | 3'UTR (SNP) | VAF 104/342 reads (30%) | catalogued as COSV68057448; called by muse, varscan2
